Somatic mutation profile of tumor specimen TCGA-RD-A7BW-01A (aliquot TCGA-RD-A7BW-01A-11D-A32N-08) from TCGA case TCGA-RD-A7BW, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 68.5 years (25,036 days).
Specimen TCGA-RD-A7BW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b28c24d-d80d-41dc-82f5-dff8ef68f998.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A7BW-10A (Blood Derived Normal), aliquot TCGA-RD-A7BW-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1e870d3-dd29-4372-bb2c-f35f15ecbe2e

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 36, Silent 14, Nonsense Mutation 6, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFBR2 | c.1271A>G p.Y424C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878854610, COSV55443795; ClinVar: pathogenic; called by muse, mutect2
- ABCA6 | c.2738C>T p.T913I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99447984; called by muse, mutect2
- AMY2B | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs568943580, COSV100796552, COSV63714957; called by muse, mutect2
- ASPRV1 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100208672; called by muse, mutect2
- C3 | c.2716G>A p.G906S | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1198580081, COSV55572592; called by muse, mutect2
- CDH9 | c.570C>A p.N190K | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV99151415; called by muse, mutect2
- CYP11A1 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as rs1454328072, CM128313, COSV51431852; called by muse, mutect2, varscan2
- DNAH9 | c.6463A>T p.T2155S | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.51); catalogued as COSV99308782; called by muse, mutect2
- EEA1 | c.1755G>C p.K585N | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100468679; called by muse, mutect2
- ELFN2 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV101297667; called by muse, mutect2, varscan2
- ELL2 | c.259A>G p.N87D | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV99427983; called by muse, mutect2
- FANCM | c.5288T>G p.F1763C | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99951807; called by muse, mutect2
- GGTLC1 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as COSV99601022; called by muse, mutect2
- IFT74 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV101197225; called by muse, mutect2
- ITGA5 | c.2939G>A p.R980H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs145576475, COSV53218138; called by muse, mutect2, varscan2
- KCNH4 | c.2722C>G p.L908V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV99238027; called by muse, mutect2, varscan2
- KCNN2 | c.719G>A p.R240Q (on ENST00000264773; = p.R452Q on NM_021614.4) | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as rs1453730945, COSV53284095; called by muse, mutect2, varscan2
- KCNQ3 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 20/187 reads (11%) | catalogued as rs919035877, COSV101196391, COSV104429886, COSV66473715; called by muse, mutect2, varscan2
- LRFN2 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100600043; called by muse, mutect2
- LRRN2 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs143481345; called by muse, mutect2
- MARCHF10 | c.1822C>A p.H608N | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100248717; called by muse, mutect2
- MYH2 | c.5580G>A p.T1860= | Splice Region (SNP) | VAF 9/93 reads (10%) | catalogued as rs761795343, COSV55452432, COSV99820574; ClinVar: uncertain significance; called by muse, mutect2
- NLGN4X | c.2123A>G p.H708R | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99324483; called by muse, mutect2, varscan2
- PCNX2 | c.836A>G p.E279G | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV99269977; called by muse, mutect2
- PLEKHM3 | c.2102C>G p.T701R | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101216972; called by muse, mutect2
- PRKCA | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV99436510; called by muse, mutect2, varscan2
- PRSS27 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.579); catalogued as rs1314343878, COSV100069761; called by muse, mutect2
- PSMG2 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV100466730; called by muse, mutect2, varscan2
- SCN4A | c.786C>A p.S262R | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101438709; called by muse, mutect2
- SF3B1 | c.3890G>A p.R1297H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1352116876, COSV59220777; called by muse, mutect2
- SLC6A20 | c.901A>C p.K301Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100654031; called by muse, mutect2, varscan2
- SOWAHD | c.857C>A p.S286* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100673189, COSV100673192; called by mutect2, varscan2
- TENM4 | c.5908C>T p.R1970C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs146739182, COSV99580555; called by muse, mutect2, varscan2
- TGFBR3 | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 39/492 reads (8%) | catalogued as COSV99283862; called by muse, mutect2
- TM9SF2 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as COSV100899793; called by muse, mutect2
- ZFHX4 | c.102A>C p.K34N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV51481442, COSV99268905; called by muse, mutect2, varscan2
- ZFHX4 | c.6553C>T p.R2185* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | catalogued as COSV51441550, COSV51500998; called by muse, mutect2, varscan2
- ZFP2 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as rs1477407864, COSV100797146; called by muse, mutect2
- ZNF471 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as rs766567776, COSV100340944; called by muse, mutect2
- ZNF518A | c.4226C>T p.T1409I | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs587759158, COSV100283788; called by muse, mutect2, varscan2
- ZNF600 | c.13G>T p.V5F | Missense Mutation (SNP) | VAF 29/377 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.166); catalogued as COSV100593130; called by muse, mutect2
- ZNF697 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1391287594, COSV70284066; called by muse, mutect2, varscan2
- IGKV1-6 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 19/296 reads (6%) | called by muse, mutect2
- MUC6 | c.4059_4065del p.T1354Pfs*100 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | called by mutect2, pindel, varscan2
- AKR1E2 | c.486G>A p.G162= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs1215297547, COSV100033714; called by muse, mutect2
- B4GALNT4 | c.1110C>T p.F370= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs906151615, COSV57322205; called by muse, mutect2, varscan2
- FYCO1 | c.2748C>T p.T916= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as rs142981160; called by muse, mutect2, varscan2
- HGS | c.1653G>A p.K551= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV100230852; called by muse, mutect2, varscan2
- KCNIP2 | c.579C>T p.D193= (on ENST00000356640 / NM_173191.3; = p.D208= on NM_014591.5) | Silent (SNP) | VAF 26/198 reads (13%) | catalogued as rs369988905; called by muse, mutect2, varscan2
- LACC1 | c.903C>T p.H301= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV100354671; called by muse, mutect2, varscan2
- MAGEB6 | c.75C>T p.L25= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV100983893; called by muse, mutect2
- MED13 | c.6132T>C p.D2044= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV101181513; called by muse, mutect2
- MUC17 | c.10485C>G p.T3495= | Silent (SNP) | VAF 57/569 reads (10%) | catalogued as COSV100072683, COSV60286810; called by muse, mutect2, varscan2
- MUC6 | c.6384C>G p.S2128= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV101424870; called by muse, mutect2, varscan2
- PSMC5 | c.876C>T p.I292= | Silent (SNP) | VAF 40/589 reads (7%) | catalogued as COSV99856707; called by muse, mutect2
- RAG1 | c.2145G>C p.V715= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV100201227; called by muse, mutect2
- ST6GAL2 | c.105C>T p.P35= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs768643816, COSV100868305; called by muse, mutect2
- TMPRSS15 | c.1578A>G p.G526= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV53044715, COSV53047423; called by muse, mutect2
